HCMI case HCM-BROD-0569-C43 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4e828c35-5fc3-40af-a2ee-10b4281c77b8

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1939; Vital status: Alive.

Diagnoses (2)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C43.9; Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Age at diagnosis: 78.3 years (28,586 days); AJCC staging edition: 8th; AJCC clinical stage: Stage III; AJCC pathologic T: T4b; AJCC pathologic N: N1b; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIC; Metastasis at diagnosis: No Metastasis; Prior malignancy: yes; Prior treatment: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Nivolumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 518 days (1.4 years); Days to treatment end: 892 days (2.4 years).
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Chemotherapy, for residual disease; adjuvant Hormone Therapy, for residual disease; adjuvant Radiation Therapy, NOS, for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.
2. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/6; ICD-10 code: C77.9; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Lymph node, NOS; Classification of tumor: metastasis; Age at diagnosis: 79.6 years (29,069 days); Days to diagnosis: 483 days (1.3 years); Satellite nodule present: Absent.
   Pathology details: Breslow thickness category: >4.0 mm; Lymph nodes positive: 1; Lymph nodes tested: 16; Lymphatic invasion present: No; Perineural invasion present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Nivolumab; Treatment intent type: Maintenance Therapy; Days to treatment start: 518 days (1.4 years); Days to treatment end: 733 days (2.0 years); Treatment outcome: Treatment Ongoing.

Follow-up (2 entries)
- Days to follow up: 1,281 days (3.5 years); Disease response: Complete Response; Progression or recurrence: No.
- Follow-up contact recording only the day: day 733.

Molecular and laboratory tests
- BRAF (IHC): Negative; Amino-acid change: V600E.
- BRAF mutation, nos: Negative.
- KIT mutation, nos: Negative.
- NRAS mutation, nos: Negative.
- TP53 mutation, nos: Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 82 kg; Height: 167 cm; BMI: 30.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-BROD-0569-C43-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-BROD-0569-C43-06A-01-S2-HE: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 3.
  Slide HCM-BROD-0569-C43-06A-01-S1-HE: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 6.
- Sample HCM-BROD-0569-C43-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0569-C43-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 10.
